Gene-level copy-number profile of tumor specimen ALCH-B1Y2-TTP1-A from ALCHEMIST case ALCH-B1Y2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.8 years (18,908 days).
Specimen ALCH-B1Y2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 39a6536b-418b-4fa6-bd3a-61b5042011a6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1Y2-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,741 have no estimate.
https://portal.gdc.cancer.gov/files/bde9bc59-5c25-44da-ad67-2d6d099f4961

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 421; copy number 1: 17,231; copy number 2: 34,970; copy number 3: 5,340; copy number 4: 909; copy number 5: 6; copy number 6: 3; copy number 7: 1; copy number 25: 1.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:47,818,066–47,820,237, 1 gene (within-gene range 0–2): AC096541.1.
- chr2:91,684,447–91,714,745, 2 genes: DRD5P1, AC027612.2.
- chr2:130,830,978–130,836,994, 1 gene (within-gene range 0–1): AC133785.1.
- chr2:131,464,900–131,536,988, 6 genes: MZT2A, TUBA3D, MIR4784, SMPD4BP, CCDC74A, MED15P4.
- chr3:46,742,092–46,750,891, 1 gene (within-gene range 0–1): PRSS45P.
- chr3:46,753,045–46,798,390, 2 genes (within-gene range 0–1): PRSS43P, AC109583.2.
- chr6:39,299,001–39,322,968, 2 genes: KCNK17, KCNK16.
- chr6:39,353,747–39,354,172, 1 gene (within-gene range 0–2): AL136087.1.
- chr7:66,511,556–66,592,397, 5 genes (within-gene range 0–2): AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1.
- chr13:99,981,784–99,986,765, 1 gene: ZIC2.
- chr13:110,641,412–110,713,603, 1 gene (within-gene range 0–1): CARS2.
- chr15:42,723,544–42,737,128, 3 genes: CDAN1, AC090510.3, AC090510.2.
- chr16:28,862,166–28,904,466, 4 genes (within-gene range 0–2): AC133550.3, ATP2A1, ATP2A1-AS1, AC133550.1.
- chr16:33,907,419–33,937,167, 1 gene: ARHGAP23P1.
- chr16:33,976,039–33,991,551, 2 genes (within-gene range 0–1): AC133561.1, BCAP31P1.
- chr16:35,143,722–35,154,366, 2 genes: AC023824.5, AC023824.6.
- chr19:17,249,171–18,014,102, 48 genes (within-gene range 0–1): USHBP1, BABAM1, AC010463.1, ANKLE1, ABHD8, MRPL34, AC010463.3, DDA1, ANO8, GTPBP3, PLVAP, AC010463.2, CCDC194, BST2, BISPR, MVB12A, AC010319.4, AC010319.1, AC010319.3, TMEM221, AC010319.2, AC010319.5, NXNL1, SLC27A1, AC010618.3, PGLS, AC010618.2, NIBAN3, COLGALT1, AC010618.1, UNC13A, AC008761.2, AC008761.3, MAP1S, AC008761.1, FCHO1, B3GNT3, INSL3, JAK3, RPL18A, SNORA68, AC005796.1, SLC5A5, CCDC124, KCNN1, RNA5SP468, ARRDC2, AC020904.3.
- chr19:22,128,627–22,141,117, 4 genes: ZNF92P2, AC073539.2, PCGF7P, MTDHP5.
- chr19:41,221,426–41,222,051, 1 gene (within-gene range 0–1): AC011510.1.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.
- chr21:43,414,483–43,427,131, 1 gene: SIK1.
- chr22:21,290,760–21,325,042, 3 genes (within-gene range 0–3): BCRP6, FAM230H, AP000552.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,699,456–143,729,570, 3 genes, copy number 5: RNVU1-17, RNVU1-23, RNVU1-18.
- chr7:105,013,425–105,014,321, 1 gene, copy number 6 (within-gene range 2–6): KMT2E-AS1.
- chr12:14,825,569–14,844,708, 2 genes, copy number 5 (within-gene range 3–5): ART4, AC007655.1.
- chr14:105,093,609–105,100,131, 2 genes, copy number 6: LINC02298, AL512356.4.
- chr17:20,814,620–20,844,257, 1 gene, copy number 5 (within-gene range 2–5): ABHD17AP6.
- chr21:43,446,601–43,453,902, 1 gene, copy number 7: LINC00319.
- chr22:21,341,595–21,345,258, 1 gene, copy number 25: PPP1R26P5.

Autosomal genes at a single copy (total copy number 1): 14,715. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
